HCMI case HCM-BROD-0595-C43 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Nevi and Melanomas; Primary site: Skin. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/87cd2ae0-d743-4c63-bbb7-694c8d12a21a

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1965; Vital status: Alive.

Diagnoses (2)
1. Malignant melanoma, NOS (the primary disease): ICD-O-3 morphology code: 8720/3; ICD-10 code: C43.9; Tissue or organ of origin: Skin, NOS; Classification of tumor: primary; Age at diagnosis: 47.2 years (17,247 days); AJCC staging edition: 8th; AJCC clinical stage: Stage IV; AJCC pathologic T: T0; AJCC pathologic M: M1c; AJCC pathologic stage: Stage 0; Metastasis at diagnosis: Metastasis, NOS; Sites of involvement: Brain, NOS / Skin / Soft tissue / Ovary, NOS.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Pembrolizumab; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 237 days; Days to treatment end: 2,133 days (5.8 years).
   Treatment given: Treatment type: Radiation, 2D Conventional; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 2,278 days (6.2 years); Days to treatment end: 2,291 days (6.3 years).
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Nivolumab; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 2,425 days (6.6 years); Days to treatment end: 2,482 days (6.8 years).
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Dabrafenib + Trametinib; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 2,524 days (6.9 years); Days to treatment end: 3,006 days (8.2 years); Treatment outcome: Treatment Ongoing.
   Recorded as not given: adjuvant Chemotherapy, for residual disease; adjuvant Hormone Therapy, for residual disease; Surgery, NOS, for initial diagnosis.
2. Malignant melanoma, NOS: ICD-O-3 morphology code: 8720/6; ICD-10 code: C79.3; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: metastasis; Age at diagnosis: 53.8 years (19,648 days); Days to diagnosis: 2,401 days (6.6 years).
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Pembrolizumab + Vemurafenib; Treatment intent type: Maintenance Therapy; Days to treatment start: 15 days; Days to treatment end: 2,111 days (5.8 years); Treatment outcome: Treatment Ongoing.

Follow-up (5 entries)
- Days to follow up: 0 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Brain, NOS; Days to progression: 0 days.
- Days to follow up: 0 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Skin, NOS; Days to progression: 0 days.
- Days to follow up: 0 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Ovary; Days to progression: 0 days.
- Days to follow up: 3,021 days (8.3 years); Disease response: Progressive Disease; Progression or recurrence: Yes.
- Follow-up contact recording only the day: day 2,425.

Molecular and laboratory tests
- BRAF mutation, nos: Positive; Amino-acid change: V600E.

Other clinical attributes
- Timepoint category: Initial Diagnosis; BMI: 19.

Exposures
- Tobacco smoking status: Current Smoker.

Family history
- Relationship type: First Degree Relative, NOS.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-BROD-0595-C43-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide HCM-BROD-0595-C43-06A-01-S1-HE: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 20; Percent stromal cells: 10; Percent lymphocyte infiltration: 4; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 3.
  Slide HCM-BROD-0595-C43-06A-01-S2-HE: Section location: Bottom; Percent tumor cells: 75; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 15; Percent stromal cells: 10; Percent lymphocyte infiltration: 4; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 3.
- Sample HCM-BROD-0595-C43-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
- Sample HCM-BROD-0595-C43-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 8.
